Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A3AP, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A3AP-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Consultation Report

Patient Name:

MRN:

DOB:

Service:

Visit #:

Accession #:

Collected:

Received:

Gender:

HCN:

Ordering MD:

Copy To:

Location:

Facility:

Reported:

Specimen(s) Received

1. Thyroid: left hemithyroid stitch upper pole

Diagnosis

Papillary carcinoma, follicular variant, 3.6 cm; mild nodular hyperplasia: Thyroid, left hemithyroidectomy specimen

Synoptic Data

Clinical History: No radiation exposure
Procedure: Left hemithyroidectomy
Received: Fresh
Specimen Integrity: Intact
Specimen Size: Left lobe:
4.3 cm
3.6 cm
2.3 cm
Isthmus +/- pyramidal lobe:
2.6 cm
0.8 cm
0.6 cm
Specimen Weight: 20.1 g
Tumor Focality: Unifocal
----- DOMINANT TUMOR -----
Tumor Laterality: Left lobe
Tumor Size: Greatest dimension: 3.6cm
Additional dimension: 3.2 cm
Additional dimension: 2.1 cm
Histologic Type: Papillary carcinoma, follicular variant
Follicular architecture
Classical cytomorphology
Histologic Grade: Not applicable

1CD-0-3
carcinoma, papillary, follicular variant
8340/3
Site: thyroid, NOS C73.9 lw
10/21/11

per JSS, follicular variant = 100%

[page 2 of 2]
Margins:	Margins uninvolved by carcinoma
Tumor Capsule:	Totally encapsulated
Tumor Capsular Invasion:	Not identified
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Not identified
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT2: Tumor more than 2 cm, but not more than 4 cm, limited to thyroid
Regional Lymph Nodes (pN):	pNX: Regional lymph nodes cannot be assigned
	Number of regional lymph nodes examined: 0
	Number of regional lymph nodes involved: 0
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	Adenomatoid nodule(s) or Nodular follicular disease
	Thyroiditis, palpation

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically verified by:

Gross Description

1. The specimen labeled with the patient's name and as "left hemithyroid stitch upper pole", consists of a left hemithyroidectomy specimen that is oriented with a suture and weighs 20.1 g. The lobe measures 4.3cm SI x 3.6 cm ML x 2.3 cm AP and the isthmus measures 2.6 SI x 0.8 cm ML x 0.6 cm AP. The external surfaces have fibrous adhesions and are painted with blue dye. No parathyroid glands or no lymph nodes are identified grossly. The mid superior lobe contains one well delineated nodule that measures 3.6 cm SI x 3.2 cm ML x 2.1 cm AP. The cut surface of the nodule has a variegated red-brown color and has a soft and flabby consistency. The remainder of the thyroid tissue is homogenous and grossly unremarkable. Sections of nodule and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:

1A-J lobe, superior to inferior
1K isthmus

Source: NCI Genomic Data Commons file 66a18972-dcd2-47d1-8d1f-780caf449ce9 (TCGA-EM-A3AP.10520066-D640-420F-B717-24B60B3F7465.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).